Somatic mutation profile of tumor specimen 0DSL09 from CCDI case PBCIAB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 19.7 years (7,189 days).
Specimen 0DSL09: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0860e351-ab25-44aa-a713-fa43680098d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSKZI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ded6a8ad-246e-4020-8bbf-280b37cdbb19

The open-access MAF lists 25 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 5, Intron 3, Nonsense Mutation 1, 5'UTR 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACOT12 | c.592G>A p.G198R | Missense Mutation (SNP) | VAF 78/256 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs772516081; called by muse, mutect2, varscan2
- CC2D2B | c.1771C>T p.P591S | Missense Mutation (SNP) | VAF 91/246 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.177); catalogued as rs565246314; called by muse, mutect2, varscan2
- HMCN2 | c.13817C>T p.A4606V | Missense Mutation (SNP) | VAF 70/158 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.11); catalogued as rs769556003; called by muse, mutect2
- KDM5C | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 16/394 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV100855492, COSV62890801; called by muse, mutect2
- KMT2B | c.7895G>A p.R2632H | Missense Mutation (SNP) | VAF 9/186 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53076014; called by muse, mutect2
- KRT81 | c.1508G>A p.R503Q | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.885); catalogued as rs138935547; called by muse, mutect2, varscan2
- SHPRH | c.1006C>T p.R336* | Nonsense Mutation (SNP) | VAF 71/163 reads (44%) | catalogued as rs755201463, COSV99262586; called by muse, mutect2, varscan2
- UBE3D | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 117/260 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs577659762; called by muse, mutect2, varscan2
- DIAPH3 | c.2739C>T p.V913= (on ENST00000400324 / NM_001042517.2; = p.V650= on NM_030932.3) | Splice Region (SNP) | VAF 103/318 reads (32%) | called by muse, mutect2, varscan2
- KIF7 | c.3040_3042del p.K1014del | In Frame Del (DEL) | VAF 38/108 reads (35%) | called by mutect2, varscan2
- NF1 | c.5228C>A p.A1743D (on ENST00000358273 / NM_001042492.3; = p.A1722D on NM_000267.3) | Missense Mutation (SNP) | VAF 91/211 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PRKAR1A | c.605A>T p.E202V | Missense Mutation (SNP) | VAF 270/311 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBMXL3 | c.1924A>C p.S642R | Missense Mutation (SNP) | VAF 84/264 reads (32%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.139); called by mutect2, varscan2
- SFMBT2 | c.2474C>A p.T825K | Missense Mutation (SNP) | VAF 143/349 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- THOC2 | c.1811T>A p.L604H | Missense Mutation (SNP) | VAF 68/261 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRERF1 | c.1685C>A p.P562H | Missense Mutation (SNP) | VAF 132/349 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CRYBG3 | c.5253C>A p.G1751= | Silent (SNP) | VAF 73/169 reads (43%) | called by muse, mutect2, varscan2
- FNIP2 | c.975A>T p.A325= | Silent (SNP) | VAF 162/348 reads (47%) | called by muse, mutect2, varscan2
- GRM5 | c.3276G>A p.P1092= (on ENST00000305447 / NM_001143831.2; = p.P1060= on NM_000842.4) | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as rs1290931665; called by muse, mutect2, varscan2
- MYBPC2 | c.480C>T p.A160= | Silent (SNP) | VAF 133/284 reads (47%) | called by muse, mutect2, varscan2
- TIMELESS | c.189C>T p.S63= | Silent (SNP) | VAF 78/185 reads (42%) | catalogued as rs369162799; called by muse, mutect2, varscan2
- CLK1 | c.162-27C>G | Intron (SNP) | VAF 41/134 reads (31%) | called by muse, mutect2, varscan2
- MROH6 | c.1644+53C>T | Intron (SNP) | VAF 35/82 reads (43%) | called by mutect2, varscan2
- REV1 | c.2346-88A>G | Intron (SNP) | VAF 7/27 reads (26%) | catalogued as rs957965496; called by muse, mutect2, varscan2
- STK31 | c.-11G>A | 5'UTR (SNP) | VAF 108/274 reads (39%) | catalogued as COSV63460912; called by muse, mutect2, varscan2
